Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4366, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4366-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Antrum. Tumor configuration: Ulcerating. Tumor size: 16 x 12 x 5 cm. Histologic type: Adenocarcinoma. Histologic grade: Moderately differentiated. Extent of invasion: Not specified. Lymph nodes: Not specified. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 37b2c232-cef4-41aa-9d38-81f129e7666d (TCGA-BR-4366.768D70A9-094F-4A0D-992E-CDC1D91341DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).